Somatic mutation profile of tumor specimen HTMCP-03-06-02158-01A (aliquot HTMCP-03-06-02158-01A-01D-6194) from CGCI case HTMCP-03-06-02158, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02158-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aca244f-ac93-4ff8-b1e1-bb92936994b1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02158-10A (Blood Derived Normal), aliquot HTMCP-03-06-02158-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06fd005c-2b95-438c-879c-0f33ccafd096

The open-access MAF lists 62 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, Splice Site 2, Nonsense Mutation 1, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2B | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774158462; called by mutect2, varscan2
- ATP7A | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as CM131221; called by muse, mutect2, varscan2
- CDH2 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201382169, COSV52274748, COSV52293811; called by muse, mutect2, varscan2
- CEP192 | c.7569G>C p.K2523N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.718); catalogued as rs1357719905; called by muse, mutect2, varscan2
- CHD2 | c.4269G>C p.K1423N | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); catalogued as COSV101245211; called by muse, mutect2, varscan2
- COL1A2 | c.3269G>T p.G1090V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM091167, COSV51956350; called by muse, mutect2, varscan2
- CUL2 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.497); catalogued as COSV66079770; called by muse, varscan2
- DNAH1 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs775935898; called by muse, mutect2, varscan2
- EPHB1 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101213321; called by muse, mutect2, varscan2
- KALRN | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767954772, COSV53773110; called by muse, mutect2, varscan2
- KCNMA1 | c.3587C>T p.S1196L (on ENST00000286628 / NM_001161352.2; = p.S1138L on NM_002247.4) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs754602276; called by muse, mutect2, varscan2
- KIF4A | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs966046535, COSV100979357; called by muse, mutect2, varscan2
- LAMA5 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs753478596; called by muse, varscan2
- MYH13 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs755306372, COSV52824168; called by muse, mutect2
- NUP155 | c.3929G>A p.R1310Q (on ENST00000231498 / NM_153485.3; = p.R1251Q on NM_004298.4) | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs768431722; called by muse, mutect2, varscan2
- PDZD2 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56854841; called by muse, mutect2, varscan2
- RTL9 | c.2306C>A p.T769K | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV71825518; called by muse, mutect2, varscan2
- SRPK2 | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV67002218; called by muse, mutect2
- AFF2 | c.2913+1G>A p.X971_splice | Splice Site (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- ANKRD30B | c.3208-2A>G p.X1070_splice | Splice Site (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- ATP1A3 | c.1207G>A p.A403T (on ENST00000545399 / NM_001256214.2; = p.A390T on NM_152296.5) | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- COL5A1 | c.5512G>A p.G1838S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL2 | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.082); called by muse, varscan2
- CUL9 | c.7187C>T p.S2396F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by muse, varscan2
- FRMPD2 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- KAT6B | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.169); called by muse, varscan2
- MAP2 | c.5176G>C p.E1726Q | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO18B | c.6789G>C p.Q2263H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- NBPF12 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 54/366 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- PHEX | c.935T>C p.F312S | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ROCK1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RTTN | c.6093G>A p.M2031I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RYR3 | c.7253C>T p.S2418F (on ENST00000389232; = p.S2419F on NM_001036.6) | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- SEC24C | c.3144+7C>G | Splice Region (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- SH2D5 | c.859A>T p.S287C (on ENST00000444387 / NM_001103161.2; = p.S203C on NM_001103160.2) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SPAG1 | c.357G>C p.E119D | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D1 | c.1402G>C p.E468Q | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TET1 | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 42/226 reads (19%) | called by muse, mutect2, varscan2
- TICRR | c.4489G>C p.E1497Q | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TPP2 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- VPS13B | c.2063T>C p.L688S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF292 | c.3420G>C p.Q1140H | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZNF546 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZNF599 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZNF708 | c.1466C>G p.S489C | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ABCC5 | c.3006C>T p.F1002= | Silent (SNP) | VAF 19/269 reads (7%) | called by muse, mutect2
- ARFGEF1 | c.4257T>C p.Y1419= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs771760657; called by muse, mutect2, varscan2
- DNAH17 | c.6957C>T p.I2319= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs761415811; called by muse, mutect2, varscan2
- EPC2 | c.561G>C p.G187= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- FRMPD4 | c.1353C>T p.I451= | Silent (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- GRIN2D | c.567C>T p.A189= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54382270; called by muse, mutect2, varscan2
- LAMA1 | c.5907G>C p.L1969= | Silent (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- SI | c.3570G>A p.G1190= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs868505324, COSV52297504; called by muse, mutect2, varscan2
- SPAG1 | c.2142C>T p.L714= | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- STYXL2 | c.1746C>T p.S582= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs771122589, COSV54810186; called by muse, mutect2, varscan2
- TMPRSS6 | c.66G>A p.A22= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs763330682, COSV60979009; called by muse, mutect2, varscan2
- TP53 | c.1107G>A p.L369= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- WWP2 | c.1575C>T p.F525= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs778277166, COSV63123974; called by muse, mutect2, varscan2
- ZNF292 | c.6015G>T p.V2005= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100370225; called by muse, mutect2, varscan2
- ZNF90 | c.141C>T p.V47= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs1477120629; called by muse, mutect2, varscan2
- AP005901.3 | n.251_252del | RNA (DEL) | VAF 38/278 reads (14%) | catalogued as rs1375331765; called by mutect2, pindel, varscan2
- NRK | c.4354-940T>C | Intron (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
